Gene-level copy-number profile of tumor specimen TCGA-AR-A1AK-01A from TCGA case TCGA-AR-A1AK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 70.7 years (25,825 days).
Specimen TCGA-AR-A1AK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a972d2c7-e885-4dfe-b56c-d0468d154419.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c76d55bf-2abd-4b30-891c-9f67359a739b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,344; copy number 2: 37,523; copy number 3: 7,579; copy number 4: 8,185; copy number 5: 118; copy number 6: 10; copy number 14: 33; copy number 18: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AK-01A-21D-A12N-01): tumor purity 0.47, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 185 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:63,032,503–63,671,921, 21 genes, copy number 5: AP001858.1, TUBAP7, SLC22A24, RPL29P22, SLC22A10, SLC22A25, AP001880.2, CCND2P1, AP001880.1, SLC22A9, PLAAT5, AP000484.1, AP001591.1, LGALS12, PLAAT4, PLAAT2, PLAAT3, AP000753.1, ATL3, IMMP1LP1, AP000753.2.
- chr11:65,823,022–67,421,183, 97 genes, copy number 5 (broad region; genes not listed).
- chr11:68,154,863–70,436,584, 61 genes, copy number 6–18 (broad region; genes not listed).
- chr11:70,477,277–70,706,068, 6 genes, copy number 18: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.

Autosomal genes at a single copy (total copy number 1): 6,344. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
